Somatic mutation profile of tumor specimen MP2PRT-PAVHKR-TMP1-A (aliquot MP2PRT-PAVHKR-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVHKR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,249 days).
Specimen MP2PRT-PAVHKR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5edf4c0-5b32-4f08-a533-3d815f7ca3da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHKR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHKR-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd89e51a-4e35-448a-89f9-e9973137bb5e

The open-access MAF lists 56 somatic variants for this specimen: 39 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 15, Nonsense Mutation 3, Splice Site 2, Splice Region 1, 5'UTR 1, Nonstop Mutation 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC7 | c.4157G>C p.*1386Sext*? | Nonstop Mutation (SNP) | VAF 23/275 reads (8%) | catalogued as COSV100177903; called by muse, mutect2
- CCDC9 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 248/609 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs767866607; called by muse, mutect2, varscan2
- DCDC1 | c.1779G>C p.L593F | Missense Mutation (SNP) | VAF 13/380 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1171706521, COSV100664012; called by muse, mutect2
- DST | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1466837824, COSV55031618; called by muse, mutect2, varscan2
- LGI2 | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1162820331; called by muse, mutect2
- MAB21L4 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 143/313 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs374813239; called by muse, mutect2, varscan2
- MIPEP | c.456G>C p.L152F | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66301973; called by muse, mutect2
- MUC15 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 135/283 reads (48%) | catalogued as COSV55553872; called by muse, mutect2, varscan2
- MYH2 | c.1864C>G p.Q622E | Missense Mutation (SNP) | VAF 144/398 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1375179120, COSV55448482; called by muse, mutect2, varscan2
- NRXN1 | c.4004G>A p.R1335K | Missense Mutation (SNP) | VAF 80/357 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV60512699; called by muse, mutect2, varscan2
- SIKE1 | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 12/378 reads (3%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.905); catalogued as COSV99285282; called by muse, mutect2
- TIAM1 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 100/473 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV99738465; called by muse, mutect2, varscan2
- TNIK | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 18/494 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV52674481; called by muse, mutect2
- TYMP | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 107/516 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.168); catalogued as rs768461642, COSV52687007; called by muse, mutect2, varscan2
- TYR | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 85/417 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs61753181, CM056074, CM135750, CM941343, COSV99633845; called by muse, mutect2, varscan2
- ZFHX4 | c.8801C>T p.T2934M | Missense Mutation (SNP) | VAF 189/423 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50497400; called by muse, mutect2, varscan2
- ZNF208 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as COSV68101588, COSV68107479; called by muse, mutect2, varscan2
- ADGRL4 | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 162/420 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CAB39 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 116/312 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CCDC7 | c.3437-1G>C p.X1146_splice | Splice Site (SNP) | VAF 111/274 reads (41%) | called by muse, mutect2, varscan2
- CLCA2 | c.2240G>C p.G747A | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CYP2U1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 109/345 reads (32%) | called by muse, mutect2, varscan2
- DLC1 | c.1750G>A p.D584N (on ENST00000276297 / NM_001348081.2; = p.D147N on NM_006094.5) | Missense Mutation (SNP) | VAF 286/725 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DROSHA | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- EID2 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 144/565 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- EPHA4 | c.93T>G p.V31= | Splice Region (SNP) | VAF 72/230 reads (31%) | called by muse, mutect2, varscan2
- FAT4 | c.14572G>A p.D4858N | Missense Mutation (SNP) | VAF 77/340 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- GET1-SH3BGR | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRAP2 | c.691-27_705delinsCCTGAAG p.X231_splice | Splice Site (DEL) | VAF 85/227 reads (37%) | called by pindel, varscan2*
- IGHV3-53 | c.349_350insTCCCAGAG | In Frame Ins (INS) | VAF 9/42 reads (21%) | called by mutect2, pindel
- LRBA | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC12 | c.1850C>T p.S617L (on ENST00000379442; = p.S474L on NM_001164462.1) | Missense Mutation (SNP) | VAF 126/804 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- NAP1L1 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PPP1R9A | c.1576G>C p.D526H | Missense Mutation (SNP) | VAF 170/499 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP2R2C | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 76/355 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIX3 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 200/586 reads (34%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- SLCO1B1 | c.1355G>A p.R452K | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF354A | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 79/398 reads (20%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 192/509 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ABCC12 | c.3957C>T p.L1319= | Silent (SNP) | VAF 28/544 reads (5%) | catalogued as COSV100252025, COSV100253143, COSV60916041; called by muse, mutect2
- ADRA2C | c.504C>G p.V168= | Silent (SNP) | VAF 20/686 reads (3%) | called by muse, mutect2
- AP3B2 | c.159C>T p.L53= | Silent (SNP) | VAF 104/332 reads (31%) | called by muse, mutect2, varscan2
- CIBAR1 | c.102C>T p.F34= | Silent (SNP) | VAF 26/456 reads (6%) | catalogued as COSV63897243; called by muse, mutect2
- CLRN2 | c.39G>A p.A13= | Silent (SNP) | VAF 120/355 reads (34%) | catalogued as rs764563397; called by muse, mutect2, varscan2
- GPR39 | c.747C>G p.L249= | Silent (SNP) | VAF 142/532 reads (27%) | called by muse, mutect2, varscan2
- LUM | c.531A>C p.S177= | Silent (SNP) | VAF 174/386 reads (45%) | called by muse, mutect2, varscan2
- MED13L | c.1158C>T p.L386= | Silent (SNP) | VAF 109/271 reads (40%) | catalogued as rs371359246, COSV99927498; called by muse, mutect2, varscan2
- NBEA | c.6075C>T p.I2025= | Silent (SNP) | VAF 16/442 reads (4%) | called by muse, mutect2
- PLPPR3 | c.819C>T p.I273= (on ENST00000520876 / NM_001270366.2; = p.I301= on NM_024888.2) | Silent (SNP) | VAF 98/299 reads (33%) | catalogued as rs1180432351, COSV62460915; called by muse, mutect2, varscan2
- SBF2 | c.1632C>T p.F544= | Silent (SNP) | VAF 108/285 reads (38%) | called by muse, mutect2, varscan2
- SLC19A1 | c.1338C>T p.Y446= | Silent (SNP) | VAF 28/574 reads (5%) | called by muse, mutect2
- SPOPL | c.207G>A p.L69= | Silent (SNP) | VAF 81/215 reads (38%) | catalogued as COSV54511434, COSV54516230, COSV54516640; called by muse, mutect2, varscan2
- TOMM70 | c.129G>A p.L43= | Silent (SNP) | VAF 301/728 reads (41%) | called by muse, mutect2, varscan2
- WNT3A | c.294C>T p.F98= | Silent (SNP) | VAF 151/381 reads (40%) | catalogued as rs764693672, COSV52729691; called by muse, mutect2, varscan2
- DNAJB5 | c.-68C>G | 5'UTR (SNP) | VAF 24/648 reads (4%) | called by muse, mutect2
- TRDD1 | chr14:22439015 ins TGGACCTT | 3'Flank (INS) | VAF 134/178 reads (75%) | called by pindel, varscan2
